Somatic mutation profile of tumor specimen TCGA-V5-A7RC-06A (aliquot TCGA-V5-A7RC-06A-11D-A403-09) from TCGA case TCGA-V5-A7RC, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; Tumor grade: GX; Age at diagnosis: 56.0 years (20,439 days).
Specimen TCGA-V5-A7RC-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f7422402-7b4f-422c-aa10-ea076ba3149e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V5-A7RC-10A (Blood Derived Normal), aliquot TCGA-V5-A7RC-10A-01D-A403-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f3dbce48-1710-4c1e-8e4d-1eaf2ed7a424

The open-access MAF lists 100 somatic variants for this specimen: 74 protein-altering or splice-affecting, 22 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 22, Intron 4, Frame Shift Del 3, Nonsense Mutation 2, Splice Site 2, Frame Shift Ins 2, In Frame Del 1, In Frame Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.919+1G>A p.X307_splice | Splice Site (SNP) | VAF 50/72 reads (69%) | hotspot (GDC flag); catalogued as rs1131691039, CD920913, CS107068, CS120864, COSV52683145, COSV52775982, COSV52814989; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.2239A>G p.S747G | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.012); catalogued as rs1240306616; called by muse, mutect2, varscan2
- CPSF6 | c.1611_1622dup p.D537_R540dup | In Frame Ins (INS) | VAF 62/92 reads (67%) | catalogued as rs776381672; called by mutect2, varscan2
- DCT | c.182G>A p.C61Y | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1175910242; called by muse, mutect2, varscan2
- DOCK11 | c.4916C>T p.A1639V | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs370101788, COSV52234125; called by muse, mutect2, varscan2
- DZIP3 | c.1234T>C p.F412L | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.351); catalogued as rs201610955; called by muse, mutect2, varscan2
- FMN2 | c.4865T>C p.I1622T | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as rs1298917573, COSV60414894; called by muse, mutect2, varscan2
- FOXRED2 | c.346C>A p.R116S | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.02); catalogued as rs755978039; called by muse, mutect2, varscan2
- GABRA2 | c.1191C>A p.N397K | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.91); PolyPhen benign (0.015); catalogued as COSV62915598; called by muse, mutect2, varscan2
- GABRB1 | c.434C>A p.P145H | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.891); catalogued as COSV54971082; called by mutect2, varscan2
- HNF4G | c.1051G>A p.G351R (on ENST00000354370 / NM_001330561.2; = p.G398R on NM_004133.5) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.564); catalogued as COSV62967764; called by muse, mutect2, varscan2
- JAKMIP1 | c.866G>A p.R289Q | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.455); catalogued as rs371853673, COSV51537918; called by muse, mutect2, varscan2
- MAGEC1 | c.898C>A p.Q300K | Missense Mutation (SNP) | VAF 51/89 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV53577785; called by muse, mutect2, varscan2
- PAPPA2 | c.42G>C p.L14F | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.994); catalogued as COSV100866688; called by muse, mutect2, varscan2
- PCDHGA3 | c.452G>T p.R151L | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.07); catalogued as COSV54043100; called by muse, mutect2, varscan2
- POTEF | c.1880T>C p.V627A | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1370646719; called by mutect2, varscan2
- POU4F3 | c.464T>C p.L155P | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.445); catalogued as rs766632966; called by muse, varscan2
- RBBP6 | c.3675A>G p.I1225M | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.014); catalogued as rs767099633; called by muse, mutect2, varscan2
- ROBO4 | c.2556G>T p.K852N | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs1204659212; called by muse, mutect2, varscan2
- SMC4 | c.3287A>G p.Y1096C | Missense Mutation (SNP) | VAF 89/123 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1257350404; called by muse, mutect2, varscan2
- SMPD4 | c.2143A>G p.I715V (on ENST00000409031 / NM_017951.4; = p.I686V on NM_017751.4) | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.24); PolyPhen benign (0.023); catalogued as rs553662129; called by muse, mutect2, varscan2
- SPIRE1 | c.1059A>G p.P353= | Splice Region (SNP) | VAF 5/50 reads (10%) | catalogued as rs1161748131; called by muse, mutect2
- TAS2R13 | c.295C>T p.L99F | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.364); catalogued as rs749247763; called by muse, mutect2, varscan2
- TCP1 | c.859C>G p.L287V | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.654); catalogued as rs766963421, COSV58459348; called by muse, mutect2, varscan2
- ZIC4 | c.34C>T p.R12* | Nonsense Mutation (SNP) | VAF 26/163 reads (16%) | catalogued as rs201698839; called by muse, mutect2, varscan2
- ZNF804B | c.2885C>G p.P962R | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV60821701, COSV60826402; called by muse, mutect2, varscan2
- ACSF3 | c.40T>C p.C14R | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.024); called by muse, mutect2
- AKIRIN2 | c.331T>G p.S111A | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ARHGAP36 | c.526C>G p.P176A | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ATAD2 | c.1921T>C p.S641P | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- CFAP221 | c.1135C>A p.Q379K | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- CRNKL1 | c.1775C>T p.A592V | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- DNAH2 | c.2162G>T p.G721V | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- EML3 | c.2116A>G p.I706V | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- ETAA1 | c.327del p.N110Ifs*4 | Frame Shift Del (DEL) | VAF 37/121 reads (31%) | called by mutect2, pindel, varscan2
- FAT1 | c.6195_6197del p.V2067del | In Frame Del (DEL) | VAF 12/35 reads (34%) | called by mutect2, pindel, varscan2
- FLOT2 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.034); called by mutect2, varscan2
- GALNT2 | c.691G>C p.E231Q | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- H2AC12 | c.14G>T p.G5V | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- HAX1 | c.778_799del p.A260Sfs*34 | Frame Shift Del (DEL) | VAF 14/45 reads (31%) | called by mutect2, pindel
- HMGCR | c.277+1G>C p.X93_splice | Splice Site (SNP) | VAF 8/55 reads (15%) | called by muse, mutect2, varscan2
- IKZF2 | c.1522A>G p.S508G | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- ISL1 | c.977G>T p.S326I | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- KCNJ8 | c.1034C>A p.T345N | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2
- KNDC1 | c.1966C>A p.Q656K | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LCE2B | c.161G>C p.G54A | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- LRRC4B | c.2018A>G p.H673R | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NAALADL2 | c.1765G>C p.V589L | Missense Mutation (SNP) | VAF 10/151 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0.02); called by muse, mutect2
- NOTCH3 | c.3009G>A p.W1003* | Nonsense Mutation (SNP) | VAF 17/73 reads (23%) | called by muse, mutect2, varscan2
- OR56A3 | c.118C>A p.L40I | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OTUD7B | c.734C>T p.S245L | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- PHC3 | c.503C>T p.A168V (on ENST00000494943 / NM_001308116.2; = p.A180V on NM_024947.4) | Missense Mutation (SNP) | VAF 149/204 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- PLEKHA8 | c.1385C>T p.S462F | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- PPT1 | c.698C>G p.S233C (on ENST00000433473; = p.S234C on NM_000310.4) | Missense Mutation (SNP) | VAF 825/935 reads (88%) | SIFT deleterious (0); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- PTCH1 | c.2606dup p.M869Ifs*27 | Frame Shift Ins (INS) | VAF 32/77 reads (42%) | called by mutect2, pindel, varscan2
- RPS6KA2 | c.224T>G p.L75R | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SERPINB4 | c.941T>C p.L314P | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SIGLEC7 | c.36dup p.R13Efs*10 | Frame Shift Ins (INS) | VAF 16/50 reads (32%) | called by pindel, varscan2
- SLC13A4 | c.1870G>T p.D624Y | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- SLITRK2 | c.1322C>G p.S441C | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SLITRK4 | c.299G>T p.G100V | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SMAD2 | c.527C>G p.P176R | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SMCR8 | c.473del p.I158Tfs*26 | Frame Shift Del (DEL) | VAF 17/36 reads (47%) | called by mutect2, pindel, varscan2
- SORCS1 | c.1376G>C p.R459T | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- SULT1C2 | c.549G>C p.M183I | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBC1D14 | c.1429C>T p.L477F | Missense Mutation (SNP) | VAF 47/83 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- TTN | c.61878A>C p.L20626F (on ENST00000591111; = p.L13202F on NM_003319.4) | Missense Mutation (SNP) | VAF 6/37 reads (16%) | PolyPhen possibly damaging (0.66); called by muse, mutect2
- UCHL5 | c.254A>G p.N85S | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- VSX2 | c.610A>G p.R204G | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZIK1 | c.123G>C p.W41C | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF300 | c.641A>C p.Q214P | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF518A | c.383C>T p.T128I | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF540 | c.1101T>A p.S367R | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF688 | c.664A>G p.R222G | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ATP9B | c.150G>A p.L50= | Silent (SNP) | VAF 19/144 reads (13%) | called by muse, mutect2, varscan2
- CDRT1 | c.99C>A p.V33= | Silent (SNP) | VAF 37/124 reads (30%) | called by muse, mutect2, varscan2
- CHST8 | c.1005C>T p.C335= | Silent (SNP) | VAF 20/48 reads (42%) | called by muse, mutect2, varscan2
- CLK3 | c.1893C>T p.H631= (on ENST00000395066 / NM_001130028.1; = p.H483= on NM_003992.4) | Silent (SNP) | VAF 12/20 reads (60%) | called by muse, mutect2, varscan2
- CPZ | c.1158G>A p.V386= (on ENST00000360986 / NM_001014447.3; = p.V375= on NM_003652.3) | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as rs1028411489; called by muse, mutect2, varscan2
- FANCM | c.675T>C p.Y225= | Silent (SNP) | VAF 32/61 reads (52%) | called by muse, mutect2, varscan2
- FBN2 | c.6840G>A p.P2280= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as rs377742525, COSV52545856; ClinVar: likely benign; called by muse, mutect2, varscan2
- FCSK | c.699C>T p.A233= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as rs753351332; called by muse, mutect2, varscan2
- FGF10 | c.336G>A p.E112= | Silent (SNP) | VAF 47/152 reads (31%) | catalogued as rs1268706232; called by muse, mutect2, varscan2
- LRCH4 | c.1761G>T p.V587= | Silent (SNP) | VAF 10/57 reads (18%) | called by muse, mutect2, varscan2
- MAML2 | c.1974G>A p.Q658= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs571656416, COSV73262854, COSV73262892; called by mutect2, varscan2
- MANEAL | c.621G>A p.V207= (on ENST00000373045 / NM_001113482.1; = p.C11Y on NM_152496.2) | Silent (SNP) | VAF 7/65 reads (11%) | called by muse, mutect2, varscan2
- MYF6 | c.126C>A p.S42= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV57353119; called by mutect2, varscan2
- NEK9 | c.2673G>A p.A891= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs145167526; called by muse, mutect2, varscan2
- PCDHB8 | c.1419C>T p.S473= | Silent (SNP) | VAF 16/109 reads (15%) | catalogued as rs113701735, COSV50768308; called by muse, mutect2, varscan2
- PLXNA1 | c.4830C>T p.I1610= | Silent (SNP) | VAF 16/94 reads (17%) | called by muse, mutect2, varscan2
- RNF220 | c.1560G>A p.S520= | Silent (SNP) | VAF 23/46 reads (50%) | catalogued as rs561320190; called by muse, mutect2, varscan2
- RYR2 | c.12375C>G p.V4125= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs1434635546; called by muse, mutect2, varscan2
- SLC25A11 | c.921C>T p.Y307= | Silent (SNP) | VAF 29/42 reads (69%) | called by muse, mutect2, varscan2
- SLC35G3 | c.510C>T p.I170= | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as rs749966552; called by muse, mutect2, varscan2
- STK24 | c.426A>G p.K142= | Silent (SNP) | VAF 30/96 reads (31%) | catalogued as rs768243797; called by muse, mutect2, varscan2
- ZDHHC17 | c.1740G>A p.T580= | Silent (SNP) | VAF 27/135 reads (20%) | catalogued as rs779385993; called by muse, mutect2, varscan2
- ANKS1B | c.3067-6752A>G | Intron (SNP) | VAF 8/49 reads (16%) | called by muse, mutect2, varscan2
- NACA | c.70+3484_70+3485del | Intron (DEL) | VAF 9/39 reads (23%) | called by mutect2, pindel, varscan2
- SND1 | c.1779+6756del | Intron (DEL) | VAF 15/61 reads (25%) | catalogued as COSV100689508; called by mutect2, pindel, varscan2
- XPO7 | c.492+18C>A | Intron (SNP) | VAF 15/75 reads (20%) | called by muse, mutect2, varscan2
